Surgical pathology report (de-identified scan), TCGA case TCGA-AA-3516, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-3516-01A (Primary Tumor).

*** Diagnosis / Diagnoses: ***

Right hemicolectomy specimen with an ulcerated colon carcinoma conforming to the histological type of a moderately differentiated, partially mucus-producing, colorectal adenocarcinoma, located 3.5 cm aborally from [REDACTED] and almost circularly occupying the intestinal wall over a length of 4 cm. Invasive tumor spread within all layers of the intestinal wall and extending into the neighboring mesocolic fatty tissue.

Appendix with apparent post-inflammatory fibrosis of the wall.

Oral and aboral resection margins and large omentum tumor-free.

Seven of twenty-six lymph nodes with metastases from the colon carcinoma that are restricted to the lymph nodes. Remaining lymph nodes with uncharacteristic reactive changes.

Tumor stage thus: pT3 pN2 (7/26), L0, V0; G2.

Based on histological findings sent for information purposes (Examination no. not clearly legible, findings of [REDACTED] dermatopathological test laboratory, [REDACTED], [REDACTED] there is a skin metastasis from an adenocarcinoma in a location that is not indicated. Based on the negative CK-20 results for the tumor cells, this is apparently not a skin metastasis from a colorectal carcinoma, but a skin metastasis from a primary tumor located elsewhere.

Source: NCI Genomic Data Commons file 96544559-e2b6-4527-8a6a-5d71bf3f00cb (TCGA-AA-3516.582A3C15-76F6-43A0-9C41-303E4EEADE06.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).